Somatic mutation profile of tumor specimen 0DFWC8 from CCDI case PBBSRD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,613 days).
Specimen 0DFWC8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f797c732-72ce-4bdc-b145-6c10d95bfcec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFWC9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a88b7a12-ce9a-49c4-8cf8-29c61666f65c

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LIM2 | c.388C>T p.R130C (on ENST00000596399 / NM_001161748.2; = p.R172C on NM_030657.4) | Missense Mutation (SNP) | VAF 212/871 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1568480054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 127/436 reads (29%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, varscan2
- AMER3 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774553121, COSV58468223; called by muse, mutect2, varscan2
- ANKRD12 | c.6181C>G p.P2061A | Missense Mutation (SNP) | VAF 13/508 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100042128; called by muse, mutect2
- DCAF11 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs776938647, COSV58108562; called by muse, mutect2, varscan2
- DCST1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 271/607 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV55056095; called by muse, varscan2
- F13B | c.1574C>T p.T525I | Missense Mutation (SNP) | VAF 109/616 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs367592896; called by muse, mutect2, varscan2
- LRP1B | c.1944A>T p.R648S | Missense Mutation (SNP) | VAF 153/802 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67250953; called by muse, mutect2, varscan2
- MAPK15 | c.1024-4G>A | Splice Region (SNP) | VAF 91/350 reads (26%) | catalogued as rs781898751; called by muse, mutect2, varscan2
- NBEAL2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 82/520 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV52762739; called by muse, mutect2, varscan2
- OR11L1 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 128/428 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63313792; called by muse, mutect2, varscan2
- PHF12 | c.2191C>T p.R731* | Nonsense Mutation (SNP) | VAF 174/630 reads (28%) | catalogued as COSV52018619; called by muse, mutect2, varscan2
- RTL1 | c.2641G>A p.V881I | Missense Mutation (SNP) | VAF 102/386 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1176088832; called by muse, mutect2, varscan2
- SPRYD3 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 189/936 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1399469722, COSV56853852; called by muse, mutect2, varscan2
- STAT5B | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 117/466 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs1326533398; called by muse, mutect2, varscan2
- TET3 | c.3301G>A p.V1101M | Missense Mutation (SNP) | VAF 158/642 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs748561400, COSV101327850, COSV101328023; called by muse, mutect2, varscan2
- USF1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 101/553 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99230949; called by muse, mutect2, varscan2
- VWA2 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs372729237; called by muse, mutect2, varscan2
- ADAM23 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 147/660 reads (22%) | called by muse, mutect2, varscan2
- COL5A2 | c.3091C>G p.P1031A | Missense Mutation (SNP) | VAF 192/905 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ERBB4 | c.3626T>G p.L1209R | Missense Mutation (SNP) | VAF 203/1053 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERVV-1 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FRMD4A | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 37/760 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMO7 | c.815A>G p.Q272R (on ENST00000357063; = p.Q287R on NM_005358.5) | Missense Mutation (SNP) | VAF 163/537 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC12A7 | c.1279T>A p.Y427N | Missense Mutation (SNP) | VAF 107/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TP53 | c.140_150del p.P47Rfs*6 | Frame Shift Del (DEL) | VAF 134/328 reads (41%) | called by mutect2, varscan2
- CRIP2 | c.135C>A p.A45= | Silent (SNP) | VAF 47/247 reads (19%) | called by muse, mutect2, varscan2
- FNDC10 | c.261C>T p.R87= | Silent (SNP) | VAF 79/166 reads (48%) | called by muse, mutect2, varscan2
- ITGA4 | c.720C>T p.D240= | Silent (SNP) | VAF 83/638 reads (13%) | called by muse, mutect2, varscan2
- KCP | c.1918C>A p.R640= (on ENST00000620378; = p.R700= on NM_001366122.1) | Silent (SNP) | VAF 64/247 reads (26%) | catalogued as rs992236366; called by muse, mutect2, varscan2
- UGT2A3 | c.231C>A p.V77= | Silent (SNP) | VAF 187/770 reads (24%) | called by muse, mutect2, varscan2
- INF2 | c.392-23G>A | Intron (SNP) | VAF 99/138 reads (72%) | called by muse, mutect2, varscan2
- MAF | c.*4357C>T | 3'UTR (SNP) | VAF 89/232 reads (38%) | catalogued as rs1051481382; called by muse, mutect2
- SUSD3 | c.*94G>A | 3'UTR (SNP) | VAF 6/28 reads (21%) | catalogued as rs1390801110; called by muse, mutect2, varscan2
